FM case AD10458 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/30082f1e-646e-4619-86f2-887a28524196

Female, 58.4 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the lung. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
